Somatic mutation profile of tumor specimen C3N-01802-01 (aliquot CPT0080030009) from CPTAC case C3N-01802, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 85.0 years (31,052 days).
Specimen C3N-01802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20b772d5-77a7-44c1-b9f3-d60ed21bb03e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01802-31 (Blood Derived Normal), aliquot CPT0080810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a61ac433-23b6-4190-ae9f-0c54179bf40c

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Frame Shift Del 5, Frame Shift Ins 4, Intron 4, Nonsense Mutation 3, 5'UTR 3, RNA 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 75/443 reads (17%) | catalogued as rs1011307501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM240 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 113/354 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs606231453, CM148747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFAP1L1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs146039286; called by muse, mutect2, varscan2
- ALK | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 69/447 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as rs1388736375, COSV66583047; called by muse, mutect2, varscan2
- BAP1 | c.86T>G p.V29G | Missense Mutation (SNP) | VAF 172/1611 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553646295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC173 | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs370900443; called by muse, mutect2, varscan2
- CNGA2 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770700157, COSV61704594; called by muse, mutect2, varscan2
- CSMD3 | c.3583G>A p.G1195R (on ENST00000297405 / NM_001363185.1; = p.G1091R on NM_052900.3) | Missense Mutation (SNP) | VAF 54/471 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52231204; called by muse, mutect2, varscan2
- DEFB113 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs1163243356; called by muse, mutect2
- GABRA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1164973274, COSV50099709, COSV50102525; called by muse, mutect2, varscan2
- GOLGA4 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs766263520, COSV62711787; called by muse, mutect2, varscan2
- HOXA3 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1292187242; called by muse, mutect2, varscan2
- KIF7 | c.2776C>T p.R926W | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147407072; called by muse, mutect2, varscan2
- KRT75 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs200753906; called by muse, mutect2, varscan2
- MED19 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV99762073; called by muse, mutect2, varscan2
- METTL21A | c.652T>G p.L218V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV55881610; called by muse, mutect2
- MMP9 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV63434214; called by muse, mutect2, varscan2
- MYF6 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57352610; called by muse, mutect2, varscan2
- NEMP2 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768165225; called by muse, mutect2, varscan2
- NID2 | c.3502C>T p.R1168C | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs117206856; called by muse, mutect2, varscan2
- OR52E2 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs746244350, COSV58613048; called by mutect2, varscan2
- PLEKHG4 | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 174/929 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs559749110, COSV58572405; called by muse, mutect2, varscan2
- PPP1R26 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1274929918, COSV63355856; called by muse, mutect2
- SENP6 | c.2033A>G p.E678G | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV59191821; called by muse, mutect2, varscan2
- SRGAP3 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1559836622; called by muse, mutect2, varscan2
- TAF1 | c.1403C>T p.A468V (on ENST00000373790 / NM_138923.4; = p.A489V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV52109591; called by muse, mutect2, varscan2
- TBX15 | c.1648G>T p.G550W (on ENST00000369429 / NM_001330677.2; = p.G444W on NM_152380.3) | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254728; called by muse, mutect2, varscan2
- TP53 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs922736614, COSV52696702, COSV52713465, COSV99391410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM7 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51241091; called by muse, mutect2, varscan2
- AP1B1 | c.553_554del p.S185Rfs*28 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by pindel, varscan2
- APC | c.8036C>A p.T2679N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- BDNF | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 134/568 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- COL6A3 | c.6301G>T p.G2101* | Nonsense Mutation (SNP) | VAF 60/547 reads (11%) | called by muse, mutect2, varscan2
- DLX4 | c.631G>T p.G211W (on ENST00000240306 / NM_138281.3; = p.G139W on NM_001934.3) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DNHD1 | c.7179dup p.K2394Efs*54 | Frame Shift Ins (INS) | VAF 75/272 reads (28%) | called by mutect2, pindel, varscan2
- DPP6 | c.1805A>G p.D602G (on ENST00000377770 / NM_001364500.2; = p.D540G on NM_001936.5) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCN1 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMA1 | c.6203G>A p.G2068E | Missense Mutation (SNP) | VAF 132/615 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LAMA1 | c.1608del p.R537Gfs*10 | Frame Shift Del (DEL) | VAF 160/880 reads (18%) | called by mutect2, pindel, varscan2
- LGALSL | c.147_148insAA p.P50Nfs*7 | Frame Shift Ins (INS) | VAF 77/390 reads (20%) | called by mutect2, pindel, varscan2
- LRRC4 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LTBP2 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MAGED1 | c.1969dup p.R657Kfs*5 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- PGK1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 17/593 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- PIEZO1 | c.4335+1G>A p.X1445_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- RBMXL3 | c.138C>A p.N46K | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- STARD9 | c.9689T>A p.V3230E | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1 | c.5518del p.H1840Tfs*64 (on ENST00000373790 / NM_138923.4; = p.H1861Tfs*64 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 88/317 reads (28%) | called by mutect2, pindel, varscan2
- TET1 | c.2071del p.T691Lfs*5 | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- TET2 | c.5007del p.K1669Nfs*26 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel*, varscan2
- ULK1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- WASHC4 | c.3116dup p.N1039Kfs*2 | Frame Shift Ins (INS) | VAF 26/129 reads (20%) | called by mutect2, varscan2
- ZBED3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.362); called by muse, mutect2
- C10orf90 | c.303G>A p.A101= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs1310759266, COSV52950322, COSV52953271; called by mutect2, varscan2
- CCDC15 | c.2613C>T p.I871= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as rs867042833; called by muse, mutect2, varscan2
- GPR158 | c.2622G>A p.P874= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as rs567691480, COSV100894383, COSV66274913; called by muse, mutect2, varscan2
- GRK7 | c.891G>A p.S297= | Silent (SNP) | VAF 107/405 reads (26%) | catalogued as rs769388963; called by muse, mutect2, varscan2
- ITGB1BP2 | c.723G>A p.A241= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs748832203; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP3K11 | c.1551C>T p.F517= | Silent (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- MGAT4C | c.180C>T p.S60= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- NEFH | c.120C>T p.A40= | Silent (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- OR6A2 | c.354C>G p.V118= | Silent (SNP) | VAF 14/279 reads (5%) | catalogued as rs1276420588; called by muse, mutect2
- TEX14 | c.4002T>G p.S1334= (on ENST00000240361 / NM_001201457.2; = p.S1288= on NM_031272.5) | Silent (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- WHRN | c.501C>T p.Y167= | Silent (SNP) | VAF 46/375 reads (12%) | catalogued as rs773544617, COSV54330107, COSV54334120; called by muse, mutect2, varscan2
- ZNF385A | c.306C>T p.V102= (on ENST00000338010 / NM_001130967.3; = p.V82= on NM_015481.3) | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- AC244258.1 | n.685C>A | RNA (SNP) | VAF 34/192 reads (18%) | catalogued as rs377484942; called by muse, mutect2, varscan2
- ADGRE4P | n.1455C>T | RNA (SNP) | VAF 22/80 reads (28%) | catalogued as rs779020776; called by muse, mutect2, varscan2
- BRD9 | c.401-149dup | Intron (INS) | VAF 18/184 reads (10%) | called by mutect2, pindel
- FLNA | c.-26G>A | 5'UTR (SNP) | VAF 68/331 reads (21%) | catalogued as COSV61053046; called by muse, mutect2, varscan2
- GP6 | c.*602C>A | 3'UTR (SNP) | VAF 84/648 reads (13%) | catalogued as COSV59976779; called by mutect2, varscan2
- PPL | c.-62C>T | 5'UTR (SNP) | VAF 16/27 reads (59%) | called by mutect2, varscan2
- PYROXD2 | c.147+15A>G | Intron (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- SCAF11 | c.-10C>A | 5'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- SDR16C5 | c.836+1609A>C | Intron (SNP) | VAF 60/189 reads (32%) | called by muse, mutect2, varscan2
- WDR82 | c.260-1278A>G | Intron (SNP) | VAF 32/393 reads (8%) | called by muse, mutect2
